Somatic mutation profile of tumor specimen TCGA-D1-A0ZR-01A (aliquot TCGA-D1-A0ZR-01A-21D-A10M-09) from TCGA case TCGA-D1-A0ZR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 57.9 years (21,157 days).
Specimen TCGA-D1-A0ZR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12fde719-3974-4543-a8a1-f25a554a62b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A0ZR-10A (Blood Derived Normal), aliquot TCGA-D1-A0ZR-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcde7d36-9be4-4343-899e-353225e11a43

The open-access MAF lists 62 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Nonsense Mutation 4, Splice Site 3, RNA 2, In Frame Del 2, Intron 1, Frame Shift Del 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- METTL14 | c.893G>C p.R298P | Missense Mutation (SNP) | VAF 43/107 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310162, COSV66310354; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 26/77 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SOX17 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 11/21 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52023963; called by muse, mutect2, varscan2
- ALG1 | c.752A>G p.E251G | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as COSV52156122; called by muse, mutect2
- ASB15 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs370081452; called by muse, mutect2, varscan2
- ATP11A | c.2395A>C p.M799L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV52105139; called by muse, mutect2, varscan2
- CABP2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV53708171; called by muse, mutect2, varscan2
- CHERP | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV52222055; called by muse, mutect2, varscan2
- CNST | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63619704; called by muse, mutect2, varscan2
- CSMD3 | c.6553C>A p.Q2185K (on ENST00000297405 / NM_001363185.1; = p.Q2081K on NM_052900.3) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV52090585, COSV52195233; called by muse, mutect2, varscan2
- CTCF | c.1702-1G>C p.X568_splice | Splice Site (SNP) | VAF 80/183 reads (44%) | catalogued as COSV50461368; called by muse, mutect2, varscan2
- ETV6 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67147747; called by muse, mutect2, varscan2
- EVI5 | c.1682A>T p.E561V | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs202092804; called by muse, mutect2, varscan2
- FAT2 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV55812275, COSV99941539; called by muse, mutect2, varscan2
- FERMT2 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as rs987671172, COSV58404894; called by muse, mutect2, varscan2
- FHL1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs146125558, COSV61779475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC1 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs759316968, COSV51929694; called by muse, mutect2, varscan2
- GRM5 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.838); catalogued as COSV59587970; called by muse, mutect2, varscan2
- H2AC17 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs988596815, COSV58151831; called by muse, mutect2, varscan2
- IQGAP3 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV63248878; called by muse, mutect2
- KATNIP | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as rs774261860, COSV55172501; called by muse, mutect2, varscan2
- KLHL1 | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.123); catalogued as COSV64765933; called by muse, mutect2, varscan2
- KLK4 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs772066068, COSV60675596; called by muse, mutect2, varscan2
- KNDC1 | c.1442C>G p.A481G | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); catalogued as COSV58830258; called by muse, mutect2, varscan2
- LAMB2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs764749398, COSV59730513; called by muse, mutect2, varscan2
- MCTP1 | c.2590G>T p.E864* | Nonsense Mutation (SNP) | VAF 59/125 reads (47%) | catalogued as COSV56502363; called by muse, mutect2, varscan2
- MGAT4C | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); catalogued as rs1215790191, COSV59829300; called by muse, mutect2, varscan2
- MME | c.884A>T p.D295V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64705779; called by muse, mutect2, varscan2
- PLXNB2 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442577954, COSV63779908; called by muse, mutect2, varscan2
- PPP1R32 | c.228-2A>G p.X76_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as COSV58543916; called by muse, mutect2, varscan2
- PSD2 | c.875C>A p.S292* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV51196980, COSV51197586; called by muse, mutect2, varscan2
- PSG3 | c.430+1G>A p.X144_splice | Splice Site (SNP) | VAF 63/172 reads (37%) | catalogued as rs146032744; called by muse, mutect2, varscan2
- PTEN | c.764T>G p.V255G | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as CM131941, COSV64288385, COSV64306346, COSV64310014; called by muse, mutect2, varscan2
- PXDNL | c.2948C>T p.T983M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV62476316; called by muse, mutect2, varscan2
- RTF1 | c.2090C>T p.S697F | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67477964; called by muse, mutect2
- SAFB | c.2741G>A p.R914H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.828); catalogued as rs754159539, COSV52649408; called by muse, mutect2, varscan2
- SPANXN4 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV65141073; called by muse, mutect2, varscan2
- TFIP11 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.98); catalogued as rs749547123, COSV53225349; called by muse, mutect2, varscan2
- UNC5D | c.2611A>G p.K871E | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1258419001, COSV54765611; called by muse, mutect2, varscan2
- USP38 | c.1364A>G p.Y455C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332791798, COSV61024638; called by muse, mutect2, varscan2
- XIRP1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs758984777, COSV61136635; called by muse, mutect2, varscan2
- ZBTB45 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs763909783, COSV54017785; called by muse, mutect2, varscan2
- ZNF439 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV58308302; called by muse, mutect2, varscan2
- ARNT2 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELFN2 | c.2156_2158del p.E719del | In Frame Del (DEL) | VAF 16/48 reads (33%) | called by pindel, varscan2
- EP300 | c.4468dup p.A1490Gfs*3 | Frame Shift Ins (INS) | VAF 47/138 reads (34%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1353_1391del p.E451_Y463del (on ENST00000521381 / NM_181523.3; = p.E181_Y193del on NM_181504.4) | In Frame Del (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel
- PTEN | c.981del p.A328Qfs*16 | Frame Shift Del (DEL) | VAF 19/33 reads (58%) | called by mutect2, pindel, varscan2
- ZNF658 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.048); called by muse, mutect2
- CCDC51 | c.630G>A p.L210= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV56486288; called by muse, mutect2, varscan2
- ITGB4 | c.3549C>T p.L1183= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV52321262; called by muse, mutect2, varscan2
- LRRC49 | c.900G>A p.Q300= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV53007098; called by muse, mutect2
- MGA | c.4578G>A p.R1526= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV54947700; called by muse, mutect2, varscan2
- MTF1 | c.570C>T p.H190= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs748122022, COSV65988222; called by muse, mutect2, varscan2
- NUP214 | c.2407C>T p.L803= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV63907211; called by muse, mutect2, varscan2
- P2RY10 | c.279T>C p.Y93= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV50680295; called by muse, mutect2, varscan2
- TFAP2C | c.1344C>T p.H448= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- TPTE | c.33G>A p.A11= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs757219554; called by muse, mutect2, varscan2
- TRRAP | c.8052G>A p.P2684= (on ENST00000359863 / NM_001244580.1; = p.P2666= on NM_003496.3) | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs947111888, COSV62837898; called by muse, mutect2, varscan2
- OR2W5 | n.368G>A | RNA (SNP) | VAF 74/317 reads (23%) | catalogued as rs531150001; called by muse, mutect2, varscan2
- RPL7A | c.626+130G>A | Intron (SNP) | VAF 56/115 reads (49%) | catalogued as COSV59297045; called by muse, mutect2, varscan2
- ZNF658B | n.816A>C | RNA (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
